Somatic mutation profile of tumor specimen TCGA-VQ-A94O-01A (aliquot TCGA-VQ-A94O-01A-11D-A410-08) from TCGA case TCGA-VQ-A94O, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 74.8 years (27,306 days).
Specimen TCGA-VQ-A94O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0220c0cf-ca42-48b0-ac2e-a01e707d985e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A94O-10A (Blood Derived Normal), aliquot TCGA-VQ-A94O-10A-01D-A413-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d4c55d2-5889-46e1-9424-e8f3950e1fe6

The open-access MAF lists 72 somatic variants for this specimen: 50 protein-altering or splice-affecting, 20 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 20, Nonsense Mutation 2, Frame Shift Del 2, Splice Site 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA12 | c.5222G>A p.R1741H (on ENST00000272895 / NM_173076.3; = p.R1423H on NM_015657.3) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs151239763; called by muse, mutect2, varscan2
- ACADL | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV52052679; called by muse, mutect2
- AL031777.2 | c.481G>C p.E161Q | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious, low confidence (0.05); catalogued as COSV100587264, COSV61912013, COSV61912148; called by muse, mutect2
- ALOX5 | c.1300G>A p.V434M | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs554154845, COSV65551484; called by muse, mutect2, varscan2
- ARID1B | c.2629C>T p.P877S | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.335); catalogued as rs1241434369, COSV99268189; called by muse, mutect2, varscan2
- BRINP3 | c.1895G>A p.R632H | Missense Mutation (SNP) | VAF 26/204 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs751255099, COSV66528308; called by muse, mutect2, varscan2
- CACNA2D3 | c.2259A>T p.K753N | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV99871819; called by muse, mutect2, varscan2
- CADM4 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as rs1203085411, COSV55930035; called by muse, mutect2, varscan2
- CDH23 | c.7111A>G p.T2371A | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV56452605; called by muse, mutect2, varscan2
- CFAP100 | c.1679T>G p.L560R | Missense Mutation (SNP) | VAF 29/39 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100729146; called by muse, mutect2, varscan2
- CHD5 | c.682G>A p.V228I | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs1034284360, COSV52421178; called by muse, mutect2, varscan2
- CHD9 | c.4453G>A p.D1485N | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as COSV99528915; called by muse, mutect2, varscan2
- COL22A1 | c.3242G>T p.G1081V | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100277294, COSV57332916; called by muse, mutect2
- CTCFL | c.427T>C p.Y143H | Missense Mutation (SNP) | VAF 35/224 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV99712359; called by muse, mutect2, varscan2
- DPP4 | c.757C>T p.R253W | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs182689048; called by muse, mutect2, varscan2
- DXO | c.1098C>A p.H366Q | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.699); catalogued as COSV100514614; called by muse, mutect2, varscan2
- FAM83F | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 39/110 reads (35%) | catalogued as rs1404842052, COSV100328887; called by muse, mutect2, varscan2
- FOXG1 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57394796; called by muse, mutect2
- GAPVD1 | c.1754C>T p.S585L | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.916); catalogued as COSV99782910; called by muse, mutect2, varscan2
- GPR101 | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 29/35 reads (83%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs766636946, COSV53240967; called by muse, mutect2, varscan2
- GPR89A | c.140C>T p.T47M | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs782074952, COSV100572401; called by mutect2, varscan2
- HHIPL2 | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 15/131 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs776221156, COSV58564340; called by muse, mutect2, varscan2
- KCNH7 | c.3544G>A p.V1182M | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.015); catalogued as rs144025747; called by muse, mutect2, varscan2
- KNG1 | c.1510G>A p.G504R | Missense Mutation (SNP) | VAF 14/19 reads (74%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as rs746520390, COSV99405352; called by muse, varscan2
- LIMA1 | c.1118G>A p.S373N | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV100372345; called by muse, mutect2, varscan2
- LRP1B | c.8399C>A p.A2800D | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.997); catalogued as COSV101254578; called by muse, mutect2, varscan2
- MUC17 | c.2211G>T p.M737I | Missense Mutation (SNP) | VAF 185/376 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100072462; called by muse, mutect2, varscan2
- NAPA | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.843); catalogued as COSV99645671; called by muse, mutect2
- NR5A1 | c.343G>A p.A115T | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.155); catalogued as COSV101007664; called by muse, mutect2
- NXN | c.406A>C p.I136L | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV100402884; called by muse, mutect2, varscan2
- OR2T2 | c.40G>A p.V14I | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373307163; called by muse, mutect2, varscan2
- PLEKHG7 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1484747432, COSV100760071; called by muse, mutect2, varscan2
- PLG | c.2271+2T>C p.X757_splice | Splice Site (SNP) | VAF 13/45 reads (29%) | catalogued as COSV100368998; called by muse, mutect2, varscan2
- PLTP | c.751C>T p.R251W | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.829); catalogued as rs759597997, COSV62464900; called by muse, mutect2, varscan2
- PTF1A | c.60C>G p.Y20* | Nonsense Mutation (SNP) | VAF 5/56 reads (9%) | catalogued as COSV100919575; called by muse, mutect2
- PTK2B | c.1830G>A p.M610I | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100593642, COSV100594362; called by muse, mutect2, varscan2
- SCML2 | c.1667A>G p.N556S | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99318789; called by muse, mutect2, varscan2
- SELPLG | c.1130C>T p.S377F | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as COSV57312766, COSV99947521; called by muse, mutect2
- SENP2 | c.299C>T p.S100L | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs749888052, COSV56192494, COSV56196600; called by muse, mutect2, varscan2
- SLITRK2 | c.1802C>T p.S601L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1556944777, COSV59422879; called by muse, mutect2, varscan2
- SPATA16 | c.1156C>G p.L386V | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV100651032; called by muse, mutect2, varscan2
- SRSF6 | c.902C>A p.S301Y | Missense Mutation (SNP) | VAF 46/173 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV99719662; called by muse, mutect2, varscan2
- ZMYND8 | c.901G>A p.G301R (on ENST00000311275 / NM_001363741.2; = p.G321R on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99519218; called by muse, varscan2
- ZNF219 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.045); catalogued as COSV100070182; called by muse, mutect2
- ZNF558 | c.893G>A p.G298E | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV56864251; called by muse, mutect2, varscan2
- ZNF646 | c.5318G>T p.R1773L | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.492); catalogued as COSV99762128; called by muse, varscan2
- FNDC11 | c.931_935del p.G311Rfs*17 | Frame Shift Del (DEL) | VAF 24/256 reads (9%) | called by mutect2, pindel
- MROH1 | c.3858G>A p.M1286I | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SYNRG | c.1487C>A p.P496H | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZMYM2 | c.1710_1711del p.H570Qfs*18 | Frame Shift Del (DEL) | VAF 24/75 reads (32%) | called by pindel, varscan2
- CADPS | c.943C>T p.L315= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as rs1213359053, COSV99336903; called by muse, mutect2, varscan2
- CHD7 | c.366G>A p.Q122= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV101418098; called by muse, mutect2
- DCC | c.72C>T p.S24= | Silent (SNP) | VAF 39/83 reads (47%) | catalogued as COSV101472574; called by muse, mutect2, varscan2
- ERCC1 | c.660G>A p.A220= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as rs753209831, COSV99185244; called by muse, mutect2, varscan2
- FHOD3 | c.2952C>T p.I984= (on ENST00000359247 / NM_001281739.3; = p.I1001= on NM_025135.5) | Silent (SNP) | VAF 36/61 reads (59%) | catalogued as rs767028264, COSV99940683; called by muse, mutect2, varscan2
- FRMD4A | c.2556C>T p.S852= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV100661525; called by muse, mutect2, varscan2
- GABRQ | c.789G>A p.R263= | Silent (SNP) | VAF 92/119 reads (77%) | catalogued as rs782570875, COSV100941165; called by muse, mutect2, varscan2
- GET4 | c.288G>A p.A96= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as rs765190588, COSV56256552; called by muse, mutect2, varscan2
- GLI2 | c.4248G>A p.P1416= (on ENST00000361492 / NM_001374353.1; = p.P1433= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs373445921, COSV58046538; called by muse, mutect2, varscan2
- H2AC1 | c.66G>A p.A22= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as rs199903073; called by muse, mutect2, varscan2
- KRT6B | c.642C>T p.F214= | Silent (SNP) | VAF 47/108 reads (44%) | catalogued as rs752273636, COSV52887251; called by muse, mutect2
- KRTAP4-3 | c.141C>T p.S47= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as rs78226710; called by muse, varscan2
- L3MBTL1 | c.2325C>T p.I775= (on ENST00000418998 / NM_001377303.1; = p.I685= on NM_015478.7) | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as rs1415240201, COSV100916952; called by muse, mutect2
- NPAP1 | c.1374C>T p.I458= | Silent (SNP) | VAF 24/111 reads (22%) | catalogued as rs902827866, COSV61507074; called by muse, mutect2, varscan2
- OR10G4 | c.441T>A p.T147= | Silent (SNP) | VAF 65/139 reads (47%) | catalogued as COSV57976504; called by muse, mutect2, varscan2
- OR10G8 | c.327C>T p.T109= | Silent (SNP) | VAF 80/101 reads (79%) | catalogued as rs750731891, COSV101461815; called by muse, mutect2, varscan2
- PTCH2 | c.2781C>A p.I927= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs761183703, COSV100942000; called by muse, varscan2
- RELB | c.426C>T p.Y142= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as rs770603208, COSV55510882; called by muse, mutect2, varscan2
- ZNF34 | c.1158C>T p.T386= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as rs751344003, COSV100603246; called by muse, mutect2
- ZZEF1 | c.291G>T p.L97= | Silent (SNP) | VAF 5/39 reads (13%) | catalogued as COSV100028907; called by muse, mutect2, varscan2
- PTPRN2 | c.113-42958G>A | Intron (SNP) | VAF 15/96 reads (16%) | catalogued as rs369465307, COSV66039227; called by muse, mutect2, varscan2
- SNRPN | chr15:24982011 G>A | 3'Flank (SNP) | VAF 29/222 reads (13%) | called by muse, mutect2, varscan2
